Somatic mutation profile of tumor specimen ALCH-B77F-TTP1-A (aliquot ALCH-B77F-TTP1-A-1-0-D-A96E-47) from ALCHEMIST case ALCH-B77F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.2 years (27,483 days).
Specimen ALCH-B77F-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96b6f968-3ce5-4e33-b201-a85b9a53bbe7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B77F-NB1-A (Peripheral Whole Blood; tissue type Normal), aliquot ALCH-B77F-NB1-A-1-0-D-A96E-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b933902-fd40-4421-a6c7-763cea96a808

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 28, Silent 12, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL3RA | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs754277261, COSV58430391; called by muse, mutect2, varscan2
- INPPL1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs144485030; called by muse, mutect2, varscan2
- RASSF1 | c.928C>T p.R310C (on ENST00000357043 / NM_170714.2; = p.R306C on NM_007182.5) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs369888153; called by muse, mutect2
- SI | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV52275407, COSV52282270; called by muse, mutect2, varscan2
- SLC25A47 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs768203496; called by muse, mutect2, varscan2
- ZNF628 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1017482348; called by muse, varscan2
- AC004997.1 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACACA | c.6545T>A p.I2182N | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ASIC4 | c.830C>G p.T277S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); called by muse, varscan2
- BCL3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.055); called by muse, varscan2
- CBL | c.890G>T p.C297F | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC183 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by mutect2, varscan2
- CCDC62 | c.1492T>G p.C498G | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2
- CXXC1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2
- DIP2B | c.1021T>G p.S341A | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM117A | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.289); called by muse, varscan2
- FAM229A | c.356G>A p.G119D | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (1); called by muse, varscan2
- FSIP2 | c.15864T>A p.F5288L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.302); called by muse, mutect2
- HACE1 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGLV2-8 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LILRB5 | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, varscan2
- LIMA1 | c.1329_1332del p.Q444Sfs*49 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by pindel, varscan2
- MYH15 | c.3534A>C p.K1178N | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- NEO1 | c.3601G>A p.D1201N | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PDCD7 | c.913G>T p.V305L | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SETD2 | c.3757G>T p.E1253* | Nonsense Mutation (SNP) | VAF 51/164 reads (31%) | called by muse, mutect2, varscan2
- SKIDA1 | c.1642G>T p.D548Y | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SLFN11 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- SYTL4 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TRNT1 | c.733dup p.I245Nfs*5 | Frame Shift Ins (INS) | VAF 32/158 reads (20%) | called by mutect2, varscan2
- TTC12 | c.1978C>T p.Q660* | Nonsense Mutation (SNP) | VAF 10/67 reads (15%) | called by muse, varscan2
- ZBTB24 | c.1336A>G p.K446E | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GRK5 | c.1635G>A p.P545= | Silent (SNP) | VAF 18/100 reads (18%) | catalogued as rs185837625, COSV64866921; called by muse, mutect2, varscan2
- JPH4 | c.1302C>T p.S434= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs182379018; called by mutect2, varscan2
- KCNK17 | c.588A>T p.P196= | Silent (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2
- LRP1 | c.4320C>T p.T1440= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs765634369; called by mutect2, varscan2
- NCF4 | c.981G>A p.T327= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs376148807; called by muse, mutect2, varscan2
- NTRK3 | c.984C>T p.N328= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as rs754732972, COSV58142753; called by muse, mutect2, varscan2
- OR2G2 | c.780C>T p.F260= | Silent (SNP) | VAF 14/168 reads (8%) | catalogued as COSV60741210; called by muse, mutect2
- PCDHB6 | c.1191T>C p.N397= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as rs1180220150; called by muse, mutect2, varscan2
- PXDN | c.3483G>A p.R1161= | Silent (SNP) | VAF 17/122 reads (14%) | called by muse, varscan2
- RTN4RL1 | c.543C>T p.H181= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs774811344, COSV58675029; called by muse, mutect2, varscan2
- SCARF1 | c.474G>A p.T158= | Silent (SNP) | VAF 8/52 reads (15%) | called by muse, varscan2
- URGCP | c.1582C>T p.L528= (on ENST00000453200 / NM_001077663.3; = p.L519= on NM_017920.4) | Silent (SNP) | VAF 18/98 reads (18%) | called by muse, mutect2, varscan2
